Somatic mutation profile of tumor specimen TCGA-HC-A6AO-01A (aliquot TCGA-HC-A6AO-01A-11D-A30E-08) from TCGA case TCGA-HC-A6AO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.8 years (19,298 days).
Specimen TCGA-HC-A6AO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9227212c-e220-48bb-a216-bf272f1a59af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A6AO-10A (Blood Derived Normal), aliquot TCGA-HC-A6AO-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ddd99a17-b806-4afa-afc7-18a3e3aebe01

The open-access MAF lists 37 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Intron 2, Frame Shift Del 1, Splice Site 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.128A>C p.D43A | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65316754; called by muse, mutect2, varscan2
- ADRA2A | c.187G>A p.V63M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs928033054, COSV54529350; called by muse, mutect2
- B4GALNT3 | c.2760G>T p.E920D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.05); catalogued as COSV56756471; called by mutect2, varscan2
- BCAS1 | c.1000C>A p.Q334K | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as rs749019655, COSV65083668, COSV65083914; called by muse, mutect2, varscan2
- BPI | c.772G>T p.E258* (on ENST00000262865; = p.E254* on NM_001725.3) | Nonsense Mutation (SNP) | VAF 6/70 reads (9%) | catalogued as COSV53407454; called by muse, mutect2
- CEP104 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65512691; called by muse, mutect2, varscan2
- CFAP46 | c.6011C>A p.A2004D | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV54156917; called by muse, mutect2, varscan2
- COL11A1 | c.1165T>C p.Y389H | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.191); catalogued as COSV62191923; called by muse, mutect2
- DGKA | c.1250+1G>A p.X417_splice | Splice Site (SNP) | VAF 33/98 reads (34%) | catalogued as COSV59387955; called by muse, mutect2, varscan2
- DPPA2 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs747129141, COSV101524768, COSV72118254; called by muse, mutect2, varscan2
- EML2 | c.1486G>T p.V496F | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as COSV55602674; called by muse, mutect2, varscan2
- FAM161A | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV56768022; called by muse, mutect2, varscan2
- GPATCH4 | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV58041156; called by muse, mutect2, varscan2
- KIAA0586 | c.1022A>G p.E341G (on ENST00000619416 / NM_001244190.2; = p.E356G on NM_014749.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54180431; called by muse, mutect2, varscan2
- MFSD2B | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs751215494, COSV57853996; called by muse, mutect2, varscan2
- OASL | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV57479965; called by muse, mutect2
- OR4D5 | c.817G>A p.V273M | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV58308778; called by muse, mutect2, varscan2
- PABPC5 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV57042574; called by mutect2, varscan2
- PHIP | c.2581A>T p.I861F | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51508361; called by muse, mutect2
- PLEKHH2 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV56758819; called by muse, mutect2
- TLE1 | c.2258A>G p.Y753C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64722747; called by muse, mutect2, varscan2
- ZNF337 | c.219A>C p.E73D | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV53322601; called by muse, mutect2, varscan2
- ZNF746 | c.528del p.P178Qfs*8 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as COSV61408902; called by mutect2, varscan2
- IGHV1OR21-1 | c.125A>T p.K42M | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD3 | c.10311C>T p.T3437= (on ENST00000297405 / NM_001363185.1; = p.T3268= on NM_052900.3) | Silent (SNP) | VAF 96/144 reads (67%) | catalogued as rs751007719, COSV52273061; called by muse, mutect2, varscan2
- GPR108 | c.423C>T p.P141= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs770619019, COSV51184469; called by muse, mutect2, varscan2
- MAGEA4 | c.159A>G p.E53= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV52342633; called by muse, mutect2, varscan2
- MESP2 | c.888G>A p.A296= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs374172103; called by muse, mutect2, varscan2
- NRXN2 | c.3192C>A p.G1064= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV55460599; called by muse, mutect2
- PCDHA4 | c.297C>T p.S99= | Silent (SNP) | VAF 9/162 reads (6%) | catalogued as COSV63539246, COSV63544811; called by muse, mutect2
- TINAGL1 | c.843C>T p.F281= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV54699720; called by muse, mutect2, varscan2
- TUBGCP6 | c.729G>T p.G243= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV50570042; called by muse, mutect2, varscan2
- UNC13D | c.663G>A p.T221= | Silent (SNP) | VAF 51/204 reads (25%) | catalogued as rs771266801, COSV52884022; called by muse, mutect2, varscan2
- ZNF536 | c.1050C>T p.C350= | Silent (SNP) | VAF 10/250 reads (4%) | catalogued as rs1184245042, COSV62831155; called by muse, mutect2
- MCM3 | c.222-519A>G | Intron (SNP) | VAF 6/96 reads (6%) | catalogued as COSV57718888; called by muse, mutect2
- RORA | c.196+51336G>A | Intron (SNP) | VAF 43/114 reads (38%) | catalogued as rs199986254, COSV55041734; called by muse, mutect2, varscan2
- ZNF99 | c.*286A>G | 3'UTR (SNP) | VAF 9/65 reads (14%) | catalogued as rs1340361839, COSV68056311; called by muse, mutect2, varscan2
